Somatic mutation profile of tumor specimen TARGET-10-PARCUM-09A (aliquot TARGET-10-PARCUM-09A-01D) from TARGET case TARGET-10-PARCUM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.1 years (4,056 days).
Specimen TARGET-10-PARCUM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26204012-4df4-4b78-a748-0161c60b9107.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCUM-10A (Blood Derived Normal), aliquot TARGET-10-PARCUM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad5a82a7-148d-4aa0-871b-5026b1b4392a

The open-access MAF lists 12 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 2, 3'UTR 1, Intron 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7701dup p.K2568Qfs*9 (on ENST00000358273 / NM_001042492.3; = p.K2547Qfs*9 on NM_000267.3) | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | catalogued as rs1060500295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- C1orf167 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.497); catalogued as rs973990802; called by muse, mutect2
- FAT2 | c.6709A>G p.T2237A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs1342842184; called by muse, mutect2, varscan2
- BTG1 | c.308_315delinsTGGCC p.T103_W105delinsMA | In Frame Del (DEL) | VAF 18/48 reads (38%) | called by pindel, varscan2*
- LRRC7 | c.3462C>T p.A1154= (on ENST00000651989 / NM_001370785.2; = p.A1121= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs753550558; called by muse, mutect2, varscan2
- LRRIQ1 | c.93T>C p.S31= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- PTPRG | c.2493A>G p.K831= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- SLIT3 | c.3369C>T p.C1123= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs144003142; called by muse, mutect2, varscan2
- ZNF558 | c.642G>A p.G214= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs782592800; called by muse, mutect2, varscan2
- FASTK | c.686-21G>A | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as rs1289859843; called by muse, mutect2, varscan2
- TKTL2 | c.*90A>G | 3'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- TRAV8-3 | chr14:21853006 ins CCTCCCCG | 3'Flank (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
